Surgical pathology report (de-identified scan), TCGA case TCGA-97-8171, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-8171-01A (Primary Tumor).

[page 1 of 12]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. F/S PLEURAL BIOPSY
2. F/S MEDIASTINAL PLEURAL BIOPSY
3. F/S DIAPHRAGMATIC PLEURAL BIOPSY
4. F/S RIGHT UPPER AND MIDDLE LOBE
5. STATION 9 LYMPH NODE, RIGHT
6. STATION 11 LYMPH NODE, RIGHT
7. STATION 10 LYMPH NODE, RIGHT
8. STATION 12 LYMPH NODE, RIGHT
9. STATION 4 LYMPH NODE, RIGHT
10. STATION 2 LYMPH NODE, RIGHT
11. STATION 7 LYMPH NODE, RIGHT
- SEE ADDENDUM

Reason For Addendum #1: Molecular Studies

Reason For Addendum #2: Molecular Studies

Reason For Addendum #3: Biomarker Report

DIAGNOSIS:

1. PLEURA: BIOPSY

- METASTATIC ADENOCARCINOMA WITH ACINAR PATTERN (SEE NOTE).

2. PLEURA, MEDIASTINAL: BIOPSY

- METASTATIC ADENOCARCINOMA WITH ACINAR PATTERN (SEE NOTE).

3. PLEURA, DIAPHRAGMATIC: BIOPSY

- METASTATIC ADENOCARCINOMA WITH ACINAR PATTERN (SEE NOTE).

Note (1-3): The foci of tumor are small and have low-grade cytologic features, so the morphologic differential diagnosis includes a reactive mesothelial proliferation, especially on the frozen section slides. However, immunohistochemical stains on permanent material show that the tumor cells are positive for TTF-1 while negative for calretinin, supporting the diagnosis. This case was discussed with

4. LUNG, RIGHT UPPER AND MIDDLE LOBES: BI-LOBECTOMY

- ADENOCARCINOMA, PAPILLARY PREDOMINANT (4.5 CM), SEE NOTE.

- VISCERAL PLEURAL INVASION IS PRESENT (CONFIRMED BY AN ELASTIC

[page 2 of 12]
STAIN).

- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.**
- METASTATIC ADENOCARCINOMA INVOLVING ONE OF NINE LYMPH NODES (1/9), WITH EXTRACAPSULAR EXTENSION.**

Note: The tumor consists of papillary (60%), acinar (20%), lepidic (10%) and micropapillary (10%) components and is seen in both the upper and middle lobes. Results of mutational studies will be reported in addenda.

5. LYMPH NODE, RIGHT LEVEL 9: BIOPSY

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).**

6. LYMPH NODE, RIGHT LEVEL 11: BIOPSY

- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).**

7. LYMPH NODE, RIGHT LEVEL 10: BIOPSY

- METASTATIC ADENOCARCINOMA WITH PAPILLARY AND ACINAR PATTERNS INVOLVING ONE LYMPH NODE (1/1).**

8. LYMPH NODE, RIGHT LEVEL 12: BIOPSY

- METASTATIC ADENOCARCINOMA WITH PAPILLARY AND ACINAR PATTERNS INVOLVING TWO OF THREE LYMPH NODES (2/3).**

9. LYMPH NODE, RIGHT LEVEL 4: BIOPSY

- METASTATIC ADENOCARCINOMA WITH PAPILLARY AND ACINAR PATTERNS INVOLVING TWO LYMPH NODES (2/2).**

10. LYMPH NODE, RIGHT LEVEL 2: BIOPSY

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).**

11. LYMPH NODE, RIGHT LEVEL 7: BIOPSY

- METASTATIC ADENOCARCINOMA WITH MICROPAPILLARY PATTERN INVOLVING ONE LYMPH NODE (1/1).**

Specimens: 1: F/S PLEURAL BIOPSY

2: F/S MEDIASTINAL PLEURAL BIOPSY

3: F/S DIAPHRAGMATIC PLEURAL BIOPSY

4: F/S RIGHT UPPER AND MIDDLE LOBE

5: STATION 9 LYMPH NODE, RIGHT

6: STATION 11 LYMPH NODE, RIGHT

7: STATION 10 LYMPH NODE, RIGHT

8: STATION 12 LYMPH NODE, RIGHT

[page 3 of 12]
9: STATION 4 LYMPH NODE, RIGHT
10: STATION 2 LYMPH NODE, RIGHT
11: STATION 7 LYMPH NODE, RIGHT

LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)

Middle and Upper Lobes

Procedure: Bilobectomy

Specimen Integrity: Intact

Specimen Laterality: Right

Tumor Site: Upper lobe

Middle lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma, mixed subtype

Histologic Grade: G2: Moderately differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

4.5cm

Comment(s): 2.5 cm in middle lobe and 2 cm in upper lobe.

Visceral Pleura Invasion: Present

MARGINS

Bronchial Margin

**Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by
invasive carcinoma**

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Present

LYMPH NODES

Extranodal Extension: Present

STAGE (pTNM)

Primary Tumor (pT):

**pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest
dimension surrounded by lung or visceral pleura without
bronchoscopic evidence of invasion more proximal than the lobar
bronchus (i.e., not in the main bronchus); or Tumor 5 cm or less
in greatest dimension with any of the following features of extent:
involves main bronchus, 2 cm or more distal to the carina; invades
the visceral pleura; associated with atelectasis or obstructive
pneumonitis that extends to the hilar region but does not involve the
entire lung**

Regional Lymph Nodes (pN)

**pN2: Metastasis in ipsilateral mediastinal and / or subcarinal
lymph node(s)**

Number Examined

[page 4 of 12]
21

Number Involved

7

Distant Metastases (pM):

pM1a: Separate tumor nodule(s) in contralateral lung; tumor with pleural nodules or malignant pleural (or pericardial) effusion

ADDITIONAL NON-TUMOR

Additional Pathologic Finding(s): Inflammation (specify type)

Respiratory Bronchiolitis

Emphysema

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

■ M with hx of COPD, now with a 4.5 cm right lung mass.

MACROSCOPIC DESCRIPTION:

The specimen is received in eleven parts, each labeled with the patient's name.

1. Part one is received fresh, labeled 'pleural biopsy'. It consists of three pieces of red-tan soft tissue ranging in size from 0.2 x 0.2 x 0.2 cm to 2.0 x 0.3 x 0.2 cm. The specimen is entirely submitted for frozen section and subsequently entirely submitted for permanent section.

2. Part two is received fresh, labeled 'mediastinal pleural biopsy'. It consists of one piece of red-tan soft tissue measuring 0.5 x 0.4 x 0.2 cm. The specimen is entirely submitted for frozen section and subsequently entirely submitted for permanent section.

3. Part three is received fresh, labeled 'diaphragmatic pleural biopsy'. It consists of two pieces of tan-yellow soft tissue measuring 0.2 x 0.1 x 0.1 cm and 0.1 x 0.1 x 0.1 cm. The specimen is entirely submitted for frozen section and subsequently entirely submitted for permanent section.

4. Part four is received fresh, labeled 'right upper and middle lobe rule out carcinoma'. It consists of a right upper and middle lobe of lung measuring 22 x 10 x 3.5 cm. The pleura on the middle lobe are grey-pink glistening, and mottled moderately with fine black streaks. Also noted is a puckered area measuring 2 x 2 cm. Beneath the puckered pleura is a grey-white firm tumor measuring 2.5 x 2.3 x 2 cm located between upper and middle lobe, medial aspect of the

[page 5 of 12]
lung, 1.5 cm from the bronchial resection margin of the medial lobe and 3 cm from the bronchial resection margin of the upper lobe. The mass is located 2 cm from the vascular margin of the middle lobe. Also noted is a bleb on the medial lobe measuring 2 cm in greatest dimension, located 1.5 cm from the tumor. The remainder of the middle lobe parenchyma is pink-red, crepitant and emphysematous. The upper lobe pleura is grey-pink glistening and reveals a thickened and puckered pleura measuring 2 x 2 cm located at the lower pole of the upper lobe. The remainder of the upper lobe parenchyma is pink-red, crepitant and blotchy. No nodule is grossly identified. Also noted are multiple anthracotic firm lymph nodes noted from the hilar area of upper and middle lobe ranging from 0.2 cm to 0.5 cm in greatest dimension. Frozen section performed and resubmitted for permanent section. Representative sections are submitted.

5. Part five is received in saline, labeled 'station 9 lymph node, right'. It consists of a red black lymph node measuring 1 x 0.7 x 0.5 cm. Entirely submitted in one cassette.

6. Part six is received in saline, labeled 'station 11 lymph node, right'. It consists of multiple soft red black lymph nodes, measuring 2.3 x 1.8 x 0.7 cm in aggregate. Entirely submitted in one cassette.

7. Part seven is received in saline, labeled 'station 10 lymph node, right'. It consists of one soft red black lymph node measuring 1.8 x 0.6 x 0.5 cm. Entirely submitted in one cassette.

8. Part eight is received in saline, labeled 'station 12 lymph node, right'. It consists of multiple soft red black lymph nodes, measuring 3 x 2.1 x 0.8 cm in aggregate. Entirely submitted in one cassette.

9. Part nine is received in saline, labeled 'station 4 lymph node, right '. It consists of one soft red black lymph node, measuring 1.3 x 0.7 x 0.4 cm in aggregate. Entirely submitted in one cassette.

10. Part ten is received in saline, labeled 'station 2 lymph node, right'. It consists of one soft red black lymph node, measuring 1 x 0.5 x 0.3 cm in aggregate. Entirely submitted in one cassette.

11. Part eleven is received in saline, labeled 'station 7 lymph node, right'. It consists of one soft red black lymph node, measuring 1.3 x 0.8 x 0.6 cm in aggregate. Entirely submitted in one cassette.

[page 6 of 12]
[REDACTED]

SUMMARY OF SECTIONS:

1A in toto
2A in toto
3A in toto
4A frozen section remaining of the nodule
4B bronchial margin of the middle lobe, shaved
4C vascular margin of the middle lobe, shaved
4D-4G nodule and underlying puckered pleura
4H bleb and underlying parenchyma from middle lobe
4I firm area between two lobes
4J anthracotic lymph node from middle lobe hilar area
4K bronchial margin upper lobe
4L vascular margin, upper lobe
4M-4N puckered pleura from upper lobe
4O-4P random section from upper lobe
4Q anthracotic lymph nodes from hilar area of upper lobe
5A entirely submitted
6A entirely submitted
7A entirely submitted
8A entirely submitted
9A entirely submitted
10A entirely submitted
11A entirely submitted

SPECIAL PROCEDURES:

INTRA - OPERATIVE CONSULTATION:

1. Pleural biopsy; frozen section
Pleural fibrosis with mesothelial hyperplasia and entrapped epithelial tubules, favor reactive mesothelial proliferation. Slide peer-reviewed at frozen section. Results reported by [REDACTED] at [REDACTED] and repeat-back provided by [REDACTED]
2. Mediastinal pleural biopsy; frozen section
Pleural fibrosis with mesothelial hyperplasia and entrapped atypical epithelial tubules, favor reactive mesothelial proliferation. Slide peer-reviewed at frozen section. Results reported by [REDACTED], and repeat-back provided by [REDACTED].
3. Diaphragmatic pleural biopsy; frozen section
Pleural fibrosis with mesothelial hyperplasia and entrapped

[page 7 of 12]
atypical epithelial tubules, favor reactive mesothelial proliferation. Slide peer-reviewed at frozen section. Results reported by [REDACTED] and repeat-back provided by [REDACTED].

4. Right upper, middle lobe; frozen section

Adenocarcinoma with papillary features. Results reported by Dr. [REDACTED] and repeat-back provided by [REDACTED]

ADDENDUM #1 FOR MOLECULAR TESTS:

KRAS, EGFR and ALK were sent on [REDACTED] or patient.

The test is to be performed on tissue from case [REDACTED]

[REDACTED] The case report, slides, and blocks for the cited accession number were retrieved from archives. The pathologist whose signature appears below reviewed the original pathology report, examined candidate H&E slides, and selected block 4E appropriate to the specifications of the ordered molecular analysis. x1 H&E and x9 unstained slides were prepared and forwarded to [REDACTED] where the subject molecular test will be performed. An addendum report will be issued when the results of this molecular test are available.

Addendum #1 performed by [REDACTED]

[page 8 of 12]
Electronically signed [REDACTED]

ADDENDUM 2:

MOLECULAR ONCOLOGY KRAS MUTATION ANALYSIS

Specimen #: [REDACTED]

RESULTS: Wild type gene.

INTERPRETATION: No mutations were identified at codons 12 and 13 of the KRAS gene.

COMMENT:

Mutations in the KRAS gene are reported to be associated with poor prognosis, and resistance to targeted tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer (NSCLC). KRAS mutations occur in 15-30% of NSCLC patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected. This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

Analysis of EGFR mutation or gene amplification status may provide additional information regarding this patient's probability of response to targeted tyrosine kinase inhibitor therapies, if clinically indicated. See references.

METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified

[page 9 of 12]
and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

[REDACTED]

This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be only used in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[REDACTED]

Electronically signed by: [REDACTED]

Date: [REDACTED]

Addendum #2 performed by

[REDACTED]

[page 10 of 12]
ADDENDUM 3:

EGFR Mutation Analysis

Clinical Data: Adenocarcinoma

RESULTS: Positive for the E746_A750del5 mutation in Exon 19.

INTERPRETATION: Deletion mutations in exon 19, mostly involving the LREA motif, are reported to correlate with responsiveness to EGFR tyrosine kinase inhibitor therapies in patients with non-small-cell lung carcinoma.

COMMENT: Forty percent (40%) or more cellularity is optimal for this mutation analysis. The sample submitted showed 70% tumor cellularity upon pathologist review.

E746_A750del5 corresponds to 2235_2249del15.

Mutations in the tyrosine kinase domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the samples, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or

[page 11 of 12]
negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

[REDACTED]

DISCLAIMER:

This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigation or for research. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[REDACTED]

Electronically signed by: [REDACTED]
Date: [REDACTED]

[REDACTED]

Addendum #3 performed by

[REDACTED]

Electronically signed [REDACTED]

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED]

They have not been cleared or approved by the US Food and Drug

[page 12 of 12]
Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 693874b1-b39d-4534-b178-e58e923f0e6e (TCGA-97-8171.71AA5CFF-EDA0-47D0-97D8-CAF4C02F5626.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).